Somatic mutation profile of tumor specimen TCGA-2Y-A9H6-01A (aliquot TCGA-2Y-A9H6-01A-11D-A38X-10) from TCGA case TCGA-2Y-A9H6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.4 years (24,982 days).
Specimen TCGA-2Y-A9H6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c73973f4-0b2d-4d37-bd45-afc7c580e2df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H6-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H6-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/340c0526-5b99-447f-958f-246270ddfe29

The open-access MAF lists 65 somatic variants for this specimen: 43 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 18, Frame Shift Del 3, RNA 2, Splice Site 2, 3'UTR 1, Nonsense Mutation 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP1 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1181880490, COSV99341518; called by muse, mutect2, varscan2
- AL645922.1 | c.1589G>T p.W530L | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100190932; called by muse, mutect2, varscan2
- ANKRD20A4P | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100628480; called by muse, mutect2, varscan2
- BPTF | c.6087-2A>G p.X2029_splice | Splice Site (SNP) | VAF 76/257 reads (30%) | catalogued as COSV100074484; called by muse, mutect2, varscan2
- CAMKK1 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV99340122; called by muse, mutect2, varscan2
- CCR4 | c.638T>A p.I213N | Missense Mutation (SNP) | VAF 97/177 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100447327; called by muse, mutect2, varscan2
- CHD4 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as COSV100537610; called by muse, mutect2, varscan2
- CLN8 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100486015; called by muse, mutect2
- CMPK2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372816766; called by muse, mutect2, varscan2
- CORIN | c.953G>T p.C318F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903282; called by muse, mutect2, varscan2
- CR2 | c.2591G>A p.G864D | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV100889569, COSV100889683; called by muse, mutect2, varscan2
- DLGAP1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100229097; called by muse, mutect2, varscan2
- EIF3M | c.943+1G>T p.X315_splice | Splice Site (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100024933; called by muse, mutect2
- FASN | c.3169A>G p.I1057V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as rs141517558; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV100436131; called by muse, mutect2, varscan2
- FXR2 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV100007120; called by muse, mutect2, varscan2
- HIPK3 | c.550T>A p.L184I | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV100305574; called by muse, mutect2, varscan2
- IFT88 | c.971A>G p.Y324C (on ENST00000319980 / NM_001318493.2; = p.Y315C on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100179583; called by muse, mutect2
- ITIH6 | c.3191G>C p.G1064A | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99513067; called by muse, mutect2, varscan2
- IVL | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.382); catalogued as rs541702541, COSV100908137; called by muse, mutect2, varscan2
- KIAA0895 | c.1258G>A p.D420N (on ENST00000297063 / NM_001100425.2; = p.D369N on NM_015314.3) | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99766639; called by muse, mutect2, varscan2
- KIF26B | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757742040, COSV63641830; called by muse, mutect2, varscan2
- KLHL34 | c.506C>A p.A169E | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV101069900, COSV65279629; called by muse, mutect2, varscan2
- MAGEC1 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1252863127, COSV53573792; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1222T>C p.S408P | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV99167812; called by muse, mutect2, varscan2
- NLRP12 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.515); catalogued as COSV60753498, COSV60757017; called by muse, mutect2, varscan2
- NPRL3 | c.638C>G p.T213R (on ENST00000611875 / NM_001077350.3; = p.T188R on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV101302022; called by muse, mutect2, varscan2
- OBI1 | c.1270A>G p.R424G | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99932360; called by muse, mutect2
- PCDH15 | c.4709G>A p.R1570Q (on ENST00000644397 / NM_001354429.2; = p.R1512Q on NM_001142771.2) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.255); catalogued as rs762452325, COSV100903617; called by muse, mutect2, varscan2
- PDCD6 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV99372641; called by muse, mutect2, varscan2
- POGLUT3 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV100052587; called by muse, mutect2, varscan2
- PPFIA2 | c.1022C>A p.T341K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100332495; called by muse, mutect2, varscan2
- PRR19 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100003724, COSV100003974; called by muse, mutect2, varscan2
- SPHKAP | c.4192C>A p.P1398T | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100763903, COSV60894263; called by muse, mutect2, varscan2
- TMEM259 | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369432576; called by muse, mutect2, varscan2
- TRPM7 | c.2116A>G p.M706V | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100539602; called by muse, mutect2, varscan2
- USP6 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as COSV100003534; called by muse, mutect2, varscan2
- WEE1 | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as rs147537355; called by muse, mutect2, varscan2
- BAP1 | c.344_348del p.M115Rfs*9 | Frame Shift Del (DEL) | VAF 70/155 reads (45%) | called by mutect2, pindel, varscan2
- MBD1 | c.1063_1074del p.F355_D358del (on ENST00000269468 / NM_001323950.1; = p.F332_D335del on NM_015845.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 24/107 reads (22%) | called by mutect2, varscan2
- RAD51B | c.389_399del p.N130Ifs*9 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- RASA1 | c.2036del p.R679Hfs*20 | Frame Shift Del (DEL) | VAF 47/157 reads (30%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.4160G>T p.C1387F | Missense Mutation (SNP) | VAF 72/569 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.407); called by mutect2, varscan2
- ATOH8 | c.498A>G p.S166= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV100092520; called by muse, mutect2, varscan2
- BRINP3 | c.1594C>A p.R532= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as COSV100818588, COSV66517274; called by muse, mutect2, varscan2
- CACNA1G | c.4506C>T p.D1502= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100661488; called by muse, mutect2, varscan2
- CACNG4 | c.486C>T p.S162= | Silent (SNP) | VAF 15/184 reads (8%) | catalogued as COSV100047474; called by muse, mutect2
- CDC42BPA | c.3162T>C p.C1054= (on ENST00000334218 / NM_001366019.2; = p.C1041= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs371390192, COSV62010557; called by muse, mutect2, varscan2
- EPS8L2 | c.375G>C p.T125= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV100585433; called by muse, mutect2, varscan2
- FBXL7 | c.1057C>A p.R353= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100309427, COSV61640453; called by muse, mutect2, varscan2
- LMF1 | c.51G>A p.R17= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV99234848; called by muse, mutect2, varscan2
- LRGUK | c.402A>G p.L134= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99603937; called by muse, mutect2, varscan2
- MCMDC2 | c.384T>C p.Y128= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV100551822, COSV58033251; called by muse, mutect2, varscan2
- OPTN | c.537T>G p.V179= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV99537369; called by muse, mutect2
- PPFIA3 | c.2850C>T p.G950= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as rs765574283, COSV53256982, COSV53258759; called by muse, mutect2, varscan2
- SARDH | c.771T>G p.T257= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as rs878952415, COSV100060570; called by muse, mutect2
- TIFA | c.201A>T p.R67= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV100655701; called by muse, mutect2, varscan2
- UBAP2 | c.2166G>A p.T722= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as rs1371980060, COSV100671133; called by muse, mutect2, varscan2
- YEATS2 | c.663G>A p.P221= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as rs754682316, COSV100527654; called by muse, mutect2, varscan2
- ZNF275 | c.474C>T p.P158= | Silent (SNP) | VAF 69/219 reads (32%) | catalogued as rs370281502, COSV100936195, COSV100936456; called by muse, mutect2, varscan2
- ZNF700 | c.459A>T p.A153= | Silent (SNP) | VAF 66/228 reads (29%) | catalogued as COSV99583413; called by muse, mutect2, varscan2
- ASCC1 | c.*153G>A | 3'UTR (SNP) | VAF 40/119 reads (34%) | catalogued as rs755255125, COSV100403229; called by muse, mutect2, varscan2
- DCHS2 | n.7642T>C | RNA (SNP) | VAF 61/178 reads (34%) | catalogued as COSV100601454; called by muse, mutect2, varscan2
- MAGEA5 | n.101A>T | RNA (SNP) | VAF 107/276 reads (39%) | called by muse, mutect2, varscan2
- RPN2 | c.1883+1696C>A | Intron (SNP) | VAF 38/121 reads (31%) | catalogued as COSV99411621; called by muse, mutect2, varscan2
